Surgical pathology report (de-identified scan), TCGA case TCGA-24-1564, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1564-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL

24-1564

*** Converted Case * This report may not match the original report format**

DIAGNOSIS:

OVARIES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- TUBAL DILATATION
- PAPILLARY SEROUS ADENOCARCINOMA, SEROSAL METASTASES

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA, SEROSAL METASTASES

OMENTUM, EXCISION
- PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

SOFT TISSUE, "SMALL BOWEL NODULE", BIOPSY
- PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

PERITONEAL PLAQUE, BIOPSY
- PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By Conversion

Intraoperative Consultation:

FS: Right adnexa - "Poorly differentiated malignant neoplasm, favor mullerian origin," by

Microscopic Description and Comment:

Both ovaries are involved by a poorly differentiated serous adenocarcinoma. The great majority of this tumor exhibits solid growth of pleomorphic cells punctuated by microcystic spaces. There is abundant necrosis and focal lymphovascular space involvement. The tumor involves the surfaces of both ovaries and

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

the adnexal soft tissue bilaterally. The right fallopian tube is dilated, and there is a benign paratubal cyst consistent with a hydatid of Morgagni. Tumor is identified on the surfaces of both fallopian tubes. Metastatic tumor is identified in the omentum and in the specimen submitted as small bowel nodule and peritoneal plaque. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
3. The TUMOR INVOLVES:
Right and left ovary
4. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
8. Tumor DOES involve the adjacent fallopian tube.
9. Metastatic involvement of the omentum is PRESENT.
10. The maximum dimension of tumor implants outside the true pelvis is 4.0 cm. (Enter "0" if no implants.)
11. Metastatic involvement of the uterine serosa CANNOT BE EVALUATED.
12. Metastatic involvement of the endometrium CANNOT BE EVALUATED.
13. Regional lymph node metastases CANNOT BE EVALUATED.
14. The total number of regional lymph nodes examined is 0.
15. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME	FIGO SCHEME	DEFINITION
T3c	IIIC	Macroscopic peritoneal metastasis beyond true pelvis measuring greater than 2 cm in greatest dimension, OR

THE REGIONAL LYMPH NODES are classified as:

NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

16. The FINAL AJCC/FIGO STAGE IS:

AJCC SCHEME

FIGO SCHEME

X

Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

History:

The patient is a [REDACTED] with a history of total abdominal hysterectomy in [REDACTED] for myomatous uterus and abnormal uterine bleeding. [REDACTED] is now having pelvic mass and ascites. Operative procedure: Examination under anesthesia; exploratory laparotomy; omentectomy; tumor debulking; bilateral salpingo-oophorectomy.

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to O.R. to pickup a specimen labeled 'right adnexa' consisting of an irregularly shaped lobulated mass measuring 6.0 x 4.5 x 3.5 cm. A 4.0 cm portion of putative fallopian tube is seen. A cystic structure measuring 5.0 cm in greatest dimension is associated with the mass. Cut surfaces show a variegated appearance with hemorrhagic foci. Tissue samples provided for tumor registry." [REDACTED]

Specimen(s) Received:

A: FS1-RIGHT ADNEXA
B: X1-RIGHT ADNEXA
C: LEFT ADNEXA
D: OMENTUM
E: SMALL BOWEL NODULE
F: PERITONEAL PLAQUE

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Gross Description:

The specimens are received in six containers of formalin, each labeled with the patient's name. The first container is labeled "FS." It contains two fragments of tan-white, soft tissue measuring 1.5 x 1.1 x 0.6 cm in aggregate. [REDACTED]

The second container is labeled "X, right adnexa." It contains a fragment of tan-white, soft tissue measuring 7.0 x 5.0 x 3.8 cm. A cyst cavity is identified measuring 3.0 cm in diameter. A putative fallopian tube is attached to the mass measuring 2.5 cm in length and 0.7 cm in diameter. [REDACTED]

The third container is labeled "left adnexa." It contains an ovary with attached fallopian tube. The ovary measures 2.7 x 2.0 x 1.5 cm. The fallopian tube measures 5.5 cm in length and 0.6 cm in diameter. The surface of the fallopian tube is involved by tumor. The ovary is involved by tumor, both on the surface and in parenchyma. Labeled L01 and L02 - left ovary; LT - left fallopian tube. [REDACTED]

The fourth container is labeled "omentum." It contains an omentum measuring 21 x 13 x 0.5 cm. Four tan-white, hard tumor nodules ranging from 1.5 to 4.0 cm in greatest dimensions are identified. Labeled A1, A2. [REDACTED]

The fifth container is labeled "small bowel nodule." It contains multiple fragments of tan, soft tissue measuring 3.0 x 2.5 x 1.0 cm in aggregate. [REDACTED]

The sixth container is labeled "peritoneal plaque." It contains one fragment of tan, soft tissue measuring 1.6 x 1.1 x 0.7 cm. [REDACTED]

Source: NCI Genomic Data Commons file d77b8328-e67f-4b58-84df-8053a365d49d (TCGA-24-1564.FA1C8286-2E55-4137-93AE-C19D470CE2E4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).